Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A2M2, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A2M2-01A (Primary Tumor).

Patient Name:

MRN:

Patient ID:

Surgical Pathology Report

Final

100-0-3

adenocarcinoma, NOS 8/40/3

Site: cervix, NOS 053.9

lw 8/18/11

SURGICAL PATHOLOGY REPORT FINAL WITH ADDENDUM

Patient Name: [REDACTED]

Address: [REDACTED]

Gender: F

DOB: [REDACTED]

Service: Radiation Oncology

Location: [REDACTED]

MRN: [REDACTED]

Hospital #: [REDACTED]

Patient Type: OPALL

Accession #: [REDACTED]

Taken: [REDACTED]

Received: [REDACTED]

Accessioned: [REDACTED]

Reported: [REDACTED]

Physician(s): [REDACTED], M.D.

DIAGNOSIS:

CERVIX, BIOPSY

- INVASIVE MODERATELY DIFFERENTIATED ENDOCERVICAL ADENOCARCINOMA
- THE TUMOR INVADERS THE ENTIRE TISSUE SECTION, AT LEAST 5 MM
- LYMPHVASCULAR SPACE INVASION IS PRESENT
- PERINEURAL INVASION IS NOT IDENTIFIED
- SEE COMMENT

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

[Signature], MD

Report Electronically Reviewed and signed Out By

MD

Microscopic Description and Comment:

Immunostains performed reveal that the tumor cells are diffusely positive for p16, while they are negative for vimentin and estrogen receptors. These features are in keeping with an endocervical primary.

I.D.

History:

The patient is a [REDACTED] year old woman. Operative procedure: Cervical biopsy.

Specimen(s) Received:

A: CERVIX

Gross Description:

The specimen is received in a formalin-filled container labeled "[REDACTED]" and "cervical biopsy." It consists of three pieces of tan-red hemorrhagic tissue, aggregating to 1.7 x 0.7 x 0.4 cm. Labeled A1. Jar 0.

Source: NCI Genomic Data Commons file 4298af55-4baa-4da1-a11d-b1c086bd45d4 (TCGA-C5-A2M2.716583F1-32F6-4CAC-853F-7A0773BB31F9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).